PECGS case C083-000029 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/03d20766-426b-4b04-99fe-d9be383bbdc8

Demographics
Sex at birth: female; Age at index: 43 years; Year of birth: 1974; Education level: Some High School or Less.

Diagnoses (2)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; Age at diagnosis: 42.8 years (15,633 days); AJCC pathologic stage: Stage IIA; Progression or recurrence: no.
2. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Age at diagnosis: 42.8 years (15,633 days); AJCC pathologic stage: Stage IA; Progression or recurrence: no.

Other clinical attributes
- Menopause status: Postmenopausal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0.

Biospecimens (2 samples)
- Sample C083-000029_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000029_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
